Gene-level copy-number profile of tumor specimen TCGA-D8-A1XW-01A from TCGA case TCGA-D8-A1XW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.3 years (19,478 days).
Specimen TCGA-D8-A1XW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.64573c1d-c2ff-4490-b7b6-b4b587b47ccb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1XW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c79c3bb8-d69f-4244-9861-8f341dad9f24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 4,180; copy number 2: 33,744; copy number 3: 14,397; copy number 4: 5,201; copy number 5: 2,032; copy number 20: 237.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1XW-01A-11D-A14J-01): tumor purity 0.64, ploidy 2.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,985,922–90,221,384, 21 genes: IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,269 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:186,842,704–188,154,057, 26 genes, copy number 5: ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 5: FLJ42393.
- chr6:39,792,298–50,049,929, 237 genes, copy number 20 (within-gene range 3–20) (broad region; genes not listed).
- chr8:87,540,835–145,066,685, 909 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–7,807,815, 154 genes, copy number 5 (broad region; genes not listed).
- chr10:7,833,618–7,833,957, 1 gene, copy number 5: AL353754.1.
- chr13:101,452,593–114,337,626, 196 genes, copy number 5 (broad region; genes not listed).
- chr22:27,204,211–50,801,309, 745 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
